Gene-level copy-number profile of tumor specimen TCGA-OR-A5KX-01A from TCGA case TCGA-OR-A5KX, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 25.5 years (9,298 days).
Specimen TCGA-OR-A5KX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.1acc357d-6f1e-4f1f-a752-777196037a59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/098f135a-34ef-46e7-9218-eb61e81d9656

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 2,814; copy number 3: 6,302; copy number 4: 39,250; copy number 5: 2,144; copy number 6: 7,858; copy number 7: 582; copy number 8: 65; copy number 9: 134; copy number 10: 21; copy number 11: 139; copy number 12: 14; copy number 13: 95; copy number 14: 4; copy number 16: 7; copy number 17: 41; copy number 18: 60; copy number 19: 18; copy number 20: 25; copy number 21: 13; copy number 22: 25; copy number 23: 49; copy number 24: 32; copy number 26: 31; copy number 27: 40; copy number 28: 10; copy number 30: 3; copy number 31: 8; copy number 32: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KX-01A-11D-A29H-01): tumor purity 0.92, ploidy 4.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 779 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:59,218,680–60,100,200, 1 gene, copy number 11 (within-gene range 3–11): AC007100.1.
- chr2:59,647,621–61,710,978, 45 genes, copy number 11: RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1.
- chr2:63,119,559–63,827,843, 1 gene, copy number 9 (within-gene range 3–9): WDPCP.
- chr2:63,517,892–66,200,373, 60 genes, copy number 9 (within-gene range 3–9): AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2, SPRED2, AC012370.1, AC007389.1, AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1.
- chr2:66,574,030–68,837,235, 35 genes, copy number 9 (within-gene range 3–9): LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D, AC017083.4, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1, AC015969.1, PLEK, AC127383.1, FBXO48, APLF, AC130709.1, PROKR1, ARHGAP25, LINC01890.
- chr5:659,862–1,295,068, 22 genes, copy number 22: TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:6,019,029–6,633,291, 11 genes, copy number 27: AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2.
- chr5:18,236,123–19,234,487, 11 genes, copy number 12–26: SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:21,196,720–23,263,185, 16 genes, copy number 21–31: AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2.
- chr5:23,951,348–25,190,956, 21 genes, copy number 23 (within-gene range 2–23): C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228.
- chr5:25,701,217–25,911,234, 3 genes, copy number 30: RNU6-374P, AC022418.1, MSNP1.
- chr5:28,285,964–28,287,807, 1 gene, copy number 23: LINC02103.
- chr5:29,070,496–29,106,861, 3 genes, copy number 22: AC024589.2, AC024589.1, AC024589.3.
- chr5:31,639,131–32,110,932, 13 genes, copy number 10 (within-gene range 5–10): PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14.
- chr5:32,354,350–36,347,157, 69 genes, copy number 19–27 (broad region; genes not listed).
- chr8:13,044,350–14,023,422, 15 genes, copy number 10–32: RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1.
- chr8:14,161,084–14,332,663, 4 genes, copy number 10: AC022039.1, EIF4EP5, RNU7-153P, Y_RNA.
- chr8:26,383,054–27,459,391, 20 genes, copy number 11: BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842.
- chr8:29,067,278–29,263,124, 1 gene, copy number 28 (within-gene range 2–28): KIF13B.
- chr8:29,110,573–29,632,644, 9 genes, copy number 28: AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33.
- chr8:30,921,060–31,176,138, 5 genes, copy number 19 (within-gene range 6–19): AC090281.1, AC008066.1, PURG, WRN, SUMO2P16.
- chr8:34,784,028–36,191,194, 10 genes, copy number 10–16 (within-gene range 10–27): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3.
- chr8:37,326,575–37,966,599, 24 genes, copy number 26: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3.
- chr12:64,404,392–74,728,851, 191 genes, copy number 11–24 (within-gene range 7–24) (broad region; genes not listed).
- chr14:50,237,563–50,335,558, 4 genes, copy number 9: L2HGDH, MIR4504, DMAC2L, AL359397.2.
- chr19:14,380,501–16,817,963, 137 genes, copy number 13–18 (within-gene range 4–18) (broad region; genes not listed).
- chr19:29,775,504–30,085,893, 13 genes, copy number 11: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:56,595,313–56,799,602, 1 gene, copy number 9 (within-gene range 6–9): ZIM2-AS1.
- chr19:56,669,941–57,419,994, 33 genes, copy number 9 (within-gene range 6–9): AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1, ZNF548, AC003002.3.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
